Somatic mutation profile of tumor specimen 0DPSNH from CCDI case PBCECL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 1.0 years (382 days).
Specimen 0DPSNH: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2d9d8fc-1615-4434-bba2-bc9899a48c42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPSN6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aba5d158-351b-4fd5-82f1-018f1e21d3dd

The open-access MAF lists 9 somatic variants for this specimen: 3 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 2, Intron 1, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIAA2026 | c.2381C>T p.S794L | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.954); catalogued as rs781324883, COSV101199202, COSV67353441; called by muse, mutect2, varscan2
- RYR1 | c.7949G>T p.R2650L | Missense Mutation (SNP) | VAF 126/2259 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs145733990, COSV62105637; called by muse, mutect2
- BCL11B | c.506C>G p.S169* | Nonsense Mutation (SNP) | VAF 128/271 reads (47%) | called by muse, mutect2, varscan2
- PROSER3 | c.291C>T p.S97= | Silent (SNP) | VAF 172/2458 reads (7%) | catalogued as rs371738339; called by muse, mutect2
- RYR1 | c.11958C>T p.D3986= | Silent (SNP) | VAF 124/2480 reads (5%) | catalogued as rs193922842, CM064228; called by muse, mutect2
- TADA2B | c.72C>T p.T24= | Silent (SNP) | VAF 46/118 reads (39%) | catalogued as COSV59508537; called by muse, mutect2, varscan2
- TFEB | c.1056C>T p.S352= | Silent (SNP) | VAF 96/253 reads (38%) | catalogued as rs758600931; called by muse, mutect2, varscan2
- SPATS1 | c.-4A>G | 5'UTR (SNP) | VAF 68/147 reads (46%) | called by muse, mutect2, varscan2
- TBC1D9B | c.2966-50C>T | Intron (SNP) | VAF 16/21 reads (76%) | catalogued as rs750793514, COSV62281620; called by muse, mutect2, varscan2
